Somatic mutation profile of tumor specimen TCGA-EE-A2MF-06A (aliquot TCGA-EE-A2MF-06A-11D-A21A-08) from TCGA case TCGA-EE-A2MF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.3 years (22,403 days).
Specimen TCGA-EE-A2MF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb1dad76-7629-45d1-a861-311939bf2ab2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MF-10B (Blood Derived Normal), aliquot TCGA-EE-A2MF-10B-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4a3ae83-b5d6-4a2e-a6c2-fb436c135eab

The open-access MAF lists 909 somatic variants for this specimen: 598 protein-altering or splice-affecting, 290 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 535, Silent 290, Nonsense Mutation 42, RNA 11, Splice Site 8, Splice Region 5, Frame Shift Del 4, Intron 4, 5'Flank 2, Frame Shift Ins 2, 3'UTR 2, In Frame Del 1.

Variants (750 of 909; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAF | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 46/100 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1057519786, COSV51691446, COSV51693647, COSV51695114; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.7102G>A p.E2368K | Missense Mutation (SNP) | VAF 61/139 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs140313224, COSV52337194; called by muse, mutect2, varscan2
- GAA | c.1076-1G>A p.X359_splice | Splice Site (SNP) | VAF 24/53 reads (45%) | catalogued as rs1555600050, CS064410, CS088180, COSV56407192; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 158/372 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 60/84 reads (71%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- ABCA10 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52218927; called by muse, mutect2, varscan2
- ABCA9 | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765755245, COSV60621338; called by muse, mutect2, varscan2
- ACACB | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV58129464, COSV58130111; called by muse, mutect2, varscan2
- ACAD11 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV53894051; called by muse, mutect2, varscan2
- ACSBG1 | c.663+2T>C p.X221_splice | Splice Site (SNP) | VAF 85/165 reads (52%) | catalogued as COSV51903710; called by muse, mutect2, varscan2
- ACSM1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54633354; called by muse, mutect2, varscan2
- ACSM2B | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61656997; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 303/744 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACTA1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 137/430 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64202946; called by muse, mutect2, varscan2
- ACTG2 | c.827A>C p.H276P | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61827642; called by muse, mutect2, varscan2
- ACY3 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs368510323; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAM30 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV65560479; called by muse, mutect2, varscan2
- ADAMTS12 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150194397, COSV61282940; called by muse, mutect2, varscan2
- ADD3 | c.1913T>C p.V638A (on ENST00000356080 / NM_001320591.2; = p.V606A on NM_001121.4) | Missense Mutation (SNP) | VAF 122/154 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53320855; called by muse, mutect2, varscan2
- ADGRF5 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV51930512, COSV51930891; called by muse, mutect2, varscan2
- ADGRG2 | c.2615G>A p.G872E (on ENST00000379869 / NM_001079858.3; = p.G869E on NM_005756.4) | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61337795; called by muse, mutect2, varscan2
- ADGRG4 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54950783; called by muse, mutect2, varscan2
- ADRA2B | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV69787248; called by muse, mutect2, varscan2
- AFF2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV53978859; called by muse, mutect2, varscan2
- ANK3 | c.5690C>A p.S1897Y | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as COSV55045495, COSV55046905; called by muse, varscan2
- ANKRD34B | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.084); catalogued as rs762597114, COSV58613476; called by muse, mutect2, varscan2
- ANKRD35 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.801); catalogued as COSV62909668; called by muse, mutect2, varscan2
- ANKRD55 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1203595772, COSV61944106; called by muse, mutect2, varscan2
- ANO3 | c.2063T>G p.L688W | Missense Mutation (SNP) | VAF 96/180 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56782534; called by muse, mutect2, varscan2
- ANO4 | c.326G>A p.G109E (on ENST00000392977 / NM_001286615.2; = p.G74E on NM_178826.4) | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100153203, COSV54587459; called by muse, mutect2, varscan2
- APBB1IP | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63076067; called by muse, varscan2
- APOOL | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV64271189; called by muse, mutect2, varscan2
- APPBP2 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 181/459 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV50025968; called by muse, mutect2, varscan2
- ARAP2 | c.4870C>T p.R1624* | Nonsense Mutation (SNP) | VAF 68/170 reads (40%) | catalogued as rs868517624, COSV58282896; called by muse, mutect2, varscan2
- ARAP2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV58283317; called by muse, mutect2, varscan2
- ARHGAP28 | c.1271G>A p.G424E (on ENST00000383472 / NM_001366230.1; = p.G265E on NM_001010000.3) | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369346560, COSV51632452; called by muse, mutect2, varscan2
- ARHGEF5 | c.4723C>T p.R1575C | Missense Mutation (SNP) | VAF 84/215 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs764608154, COSV50207993; called by muse, mutect2, varscan2
- ARMC4 | c.1583G>A p.R528K | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs762776809, COSV59457691, COSV59475733; called by muse, mutect2
- ARSF | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63839065; called by muse, mutect2, varscan2
- ASPM | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 75/132 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54125704; called by muse, mutect2, varscan2
- ATF6 | c.1930C>T p.Q644* | Nonsense Mutation (SNP) | VAF 104/252 reads (41%) | catalogued as COSV63406162; called by muse, mutect2, varscan2
- ATF7IP | c.3284T>C p.V1095A | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs137897287; called by muse, mutect2, varscan2
- ATP10A | c.3962C>T p.P1321L | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as COSV63514253; called by muse, mutect2, varscan2
- ATP11A | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52106904; called by muse, mutect2, varscan2
- ATP1A3 | c.2586G>A p.M862I (on ENST00000545399 / NM_001256214.2; = p.M849I on NM_152296.5) | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV100131809, COSV57485589; called by muse, mutect2, varscan2
- ATP6V0A1 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs111886720, COSV52871183; called by muse, mutect2, varscan2
- AZIN2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV53856093; called by muse, mutect2, varscan2
- BCAM | c.554G>A p.W185* | Nonsense Mutation (SNP) | VAF 68/167 reads (41%) | catalogued as COSV54300790; called by muse, mutect2, varscan2
- BCL9 | c.3116C>G p.S1039C | Missense Mutation (SNP) | VAF 81/226 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52341630; called by muse, mutect2, varscan2
- BCR | c.3321C>T p.V1107= | Splice Region (SNP) | VAF 164/180 reads (91%) | catalogued as rs529398786, COSV59927866; called by muse, mutect2, varscan2
- BMP10 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV54894222; called by muse, mutect2, varscan2
- BMP4 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.155); catalogued as COSV55415249; called by muse, mutect2, varscan2
- BMP5 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.141); catalogued as rs142884641; called by muse, mutect2, varscan2
- BRPF3 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 112/436 reads (26%) | catalogued as COSV100326019, COSV60206265; called by muse, mutect2, varscan2
- C11orf87 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59356211, COSV59357525; called by muse, mutect2, varscan2
- C1QTNF2 | c.311G>A p.R104Q (on ENST00000393975; = p.R59Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs759937511, COSV67432358; called by muse, mutect2, varscan2
- C5 | c.3587C>T p.S1196F | Missense Mutation (SNP) | VAF 69/86 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56324464; called by muse, mutect2, varscan2
- C8A | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs755705114, COSV63483242; called by muse, mutect2, varscan2
- C9 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as COSV54674629; called by muse, mutect2, varscan2
- C9orf131 | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 70/105 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs748078341, COSV100398033; called by muse, mutect2, varscan2
- CA2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs781174741, COSV53405919; called by muse, mutect2, varscan2
- CACNA1C | c.1280A>T p.K427M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59700044; called by muse, mutect2, varscan2
- CACNA2D3 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758120700, COSV55518521; called by muse, mutect2, varscan2
- CADPS | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 96/126 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51869404, COSV51895192; called by muse, mutect2, varscan2
- CAPN15 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99562376; called by muse, mutect2, varscan2
- CARD6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV54564488; called by muse, mutect2, varscan2
- CATSPER4 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV58792434; called by muse, mutect2, varscan2
- CBX6 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53320353; called by muse, mutect2, varscan2
- CCDC47 | c.1371+2T>C p.X457_splice | Splice Site (SNP) | VAF 120/299 reads (40%) | catalogued as COSV56722010; called by muse, mutect2, varscan2
- CCDC60 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs764208425, COSV59540294; called by muse, mutect2, varscan2
- CCDC60 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as rs1297066120, COSV59540844; called by muse, mutect2, varscan2
- CCDC62 | c.525T>G p.N175K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV53431059; called by muse, mutect2, varscan2
- CCDC88C | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV66234704; called by muse, varscan2
- CCNB3 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52070537, COSV52075853; called by muse, mutect2, varscan2
- CCRL2 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 95/122 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs934093878, COSV62193263; called by muse, mutect2, varscan2
- CD180 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.157); catalogued as rs1482634876, COSV56517045; called by muse, mutect2, varscan2
- CD1D | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 178/391 reads (46%) | catalogued as COSV63808501; called by muse, mutect2, varscan2
- CD2 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65643919, COSV65644749; called by muse, mutect2, varscan2
- CD300LF | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56895956; called by muse, mutect2, varscan2
- CD93 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 143/316 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as rs1365101353, COSV55663653, COSV55669574; called by muse, mutect2, varscan2
- CDH26 | c.1730T>A p.F577Y | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.108); catalogued as COSV54843492; called by muse, mutect2, varscan2
- CDK8 | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.94); catalogued as COSV67419388, COSV67419755, COSV67422527; called by muse, mutect2, varscan2
- CDKN1A | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as COSV55187404; called by muse, mutect2, varscan2
- CDYL2 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV73653874; called by muse, mutect2, varscan2
- CFAP206 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51532787; called by muse, mutect2, varscan2
- CFAP54 | c.7254T>A p.N2418K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61570922; called by muse, mutect2, varscan2
- CFAP91 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759926184, COSV56339535; called by muse, mutect2
- CFAP92 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs1392132240, COSV54046486; called by muse, mutect2, varscan2
- CFTR | c.4238T>A p.F1413Y | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV50042385; called by muse, mutect2, varscan2
- CGNL1 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 117/230 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55564208; called by muse, mutect2, varscan2
- CGNL1 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55564219; called by muse, mutect2, varscan2
- CHL1 | c.1589A>C p.H530P (on ENST00000397491 / NM_001253387.1; = p.H546P on NM_006614.4) | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.499); catalogued as COSV56587763; called by muse, mutect2, varscan2
- CHODL | c.379T>C p.S127P | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1292478093, COSV54731438; called by muse, mutect2, varscan2
- CKAP5 | c.3745C>T p.L1249F | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV56364684; called by muse, mutect2, varscan2
- CLCA4 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs779700000, COSV65282606; called by muse, mutect2, varscan2
- CLCN1 | c.1718T>G p.L573R | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58367800; called by muse, mutect2, varscan2
- CLEC17A | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.86); catalogued as rs764808677, COSV60426617; called by muse, mutect2, varscan2
- CLEC5A | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV69396857, COSV69397801; called by muse, mutect2, varscan2
- CLEC5A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396699; called by muse, mutect2, varscan2
- CLIC6 | c.1690C>T p.P564S (on ENST00000360731 / NM_001317009.2; = p.P546S on NM_053277.3) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV62447169; called by muse, mutect2, varscan2
- CLMN | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV54179546; called by muse, mutect2, varscan2
- CLPX | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV55643359; called by muse, mutect2, varscan2
- CMBL | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as COSV56982939; called by muse, mutect2, varscan2
- CNGA2 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61703488; called by muse, mutect2, varscan2
- COL11A1 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV62174708; called by muse, mutect2, varscan2
- COL11A2 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.841); catalogued as COSV59494135; called by muse, mutect2, varscan2
- COL1A1 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56802955; called by muse, mutect2, varscan2
- COL4A3 | c.3083A>G p.K1028R | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV59257571; called by muse, mutect2, varscan2
- COL4A5 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60356999; called by muse, mutect2, varscan2
- COL4A6 | c.2890A>T p.N964Y | Missense Mutation (SNP) | VAF 211/462 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV57860144; called by muse, mutect2, varscan2
- COL5A2 | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66407613; called by muse, mutect2, varscan2
- COL5A3 | c.4763C>T p.P1588L | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53406980; called by muse, mutect2, varscan2
- COL8A1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.051); catalogued as rs751168494, COSV53730201, COSV99658100; called by muse, mutect2, varscan2
- COL9A1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 163/408 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57879770; called by muse, mutect2, varscan2
- CORIN | c.1550A>C p.K517T | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56687317; called by muse, mutect2, varscan2
- CPA6 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 160/245 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52722193; called by muse, mutect2, varscan2
- CRACD | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as rs1173954381, COSV51716052; called by muse, mutect2, varscan2
- CRB1 | c.4206G>A p.M1402I | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66337047; called by muse, mutect2, varscan2
- CRP | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760410118, COSV54812566, COSV54812711; called by muse, mutect2, varscan2
- CRYBG1 | c.5589G>A p.W1863* | Nonsense Mutation (SNP) | VAF 119/169 reads (70%) | catalogued as rs1365465885, COSV64811019, COSV64813817; called by muse, mutect2, varscan2
- CSMD1 | c.7939T>A p.F2647I (on ENST00000520002; = p.F2646I on NM_033225.6) | Missense Mutation (SNP) | VAF 176/218 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV59289087; called by muse, mutect2, varscan2
- CSMD2 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53885303; called by muse, mutect2, varscan2
- CSMD2 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53885317; called by muse, mutect2, varscan2
- CSMD3 | c.4463C>T p.S1488F (on ENST00000297405 / NM_001363185.1; = p.S1384F on NM_052900.3) | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52114965; called by muse, mutect2, varscan2
- CST9L | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as rs774548597, COSV65407598; called by muse, varscan2
- CTCFL | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs757098063, COSV54771438; called by muse, mutect2, varscan2
- CXCR2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV59279870; called by muse, mutect2, varscan2
- CYP3A7 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as COSV60480711; called by muse, mutect2, varscan2
- DACT1 | c.2036G>A p.W679* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as rs903942040, COSV60019680; called by muse, mutect2, varscan2
- DAG1 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 112/133 reads (84%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs753789849, COSV58182909; called by muse, mutect2, varscan2
- DBNL | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as COSV68880222; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCN | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.067); catalogued as COSV50006192; called by muse, mutect2, varscan2
- DCSTAMP | c.1231A>G p.S411G | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1288671494, COSV99886435; called by muse, mutect2, varscan2
- DENND2C | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV67920237; called by muse, mutect2, varscan2
- DENND4A | c.3220A>T p.S1074C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV71265344; called by muse, mutect2, varscan2
- DGKK | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65706575; called by muse, mutect2, varscan2
- DHX29 | c.2927T>C p.L976S | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as COSV52416871; called by muse, mutect2, varscan2
- DISP3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as rs748281559, COSV53821686; called by muse, mutect2, varscan2
- DMBT1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 304/399 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371683770; called by muse, mutect2, varscan2
- DMBT1 | c.6056C>T p.S2019L (on ENST00000338354 / NM_001377530.1; = p.S1262L on NM_004406.3) | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.895); catalogued as COSV57536402; called by muse, mutect2, varscan2
- DNAH5 | c.2026C>T p.L676F | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV54207798; called by muse, mutect2, varscan2
- DNAH8 | c.5636G>A p.R1879K | Missense Mutation (SNP) | VAF 90/331 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59429257; called by muse, mutect2, varscan2
- DNAH9 | c.9821G>A p.R3274K | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52337211; called by muse, mutect2, varscan2
- DNAJC10 | c.1673T>G p.V558G | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51136092; called by muse, mutect2, varscan2
- DNAJC14 | c.205C>G p.H69D | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV57912299; called by muse, mutect2, varscan2
- DOCK11 | c.5681C>T p.S1894L | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.164); catalogued as rs1167815578, COSV52234581; called by muse, mutect2, varscan2
- DOCK8 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV66632992; called by muse, mutect2, varscan2
- DPP6 | c.1027C>T p.H343Y (on ENST00000377770 / NM_001364500.2; = p.H281Y on NM_001936.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV59600491; called by muse, mutect2
- DSG1 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1003656800, COSV57133644; called by muse, mutect2, varscan2
- DSP | c.8261G>A p.G2754E | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV60938822; called by muse, mutect2, varscan2
- DST | c.22028G>A p.R7343Q (on ENST00000361203 / NM_001374722.1; = p.R5053Q on NM_015548.5) | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs372639720, COSV55013488; called by muse, mutect2, varscan2
- EBF2 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | catalogued as COSV68776356; called by muse, mutect2, varscan2
- EDNRA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 77/183 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs867143675, COSV60095964; called by muse, mutect2, varscan2
- EGF | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54476244; called by muse, mutect2, varscan2
- EGFL6 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 95/201 reads (47%) | catalogued as COSV63632980; called by muse, mutect2, varscan2
- EGFR | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs866460345, COSV51776559; called by muse, varscan2
- EGFR | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51776578; called by muse, varscan2
- EGR4 | c.1525G>A p.G509S (on ENST00000545030; = p.G406S on NM_001965.4) | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71531926; called by muse, mutect2, varscan2
- EHF | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs752457173, COSV57667684; called by muse, mutect2, varscan2
- EIF2AK4 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.995); catalogued as COSV55465653; called by muse, mutect2, varscan2
- ELMO1 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60296957; called by muse, mutect2, varscan2
- EML4 | c.682A>G p.K228E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59294386; called by muse, mutect2, varscan2
- ENO2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50386972; called by muse, mutect2, varscan2
- EPHA4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56027663; called by muse, mutect2, varscan2
- EPHB2 | c.1127G>C p.G376A | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV65860238; called by muse, mutect2, varscan2
- EPHB3 | c.2852T>G p.F951C | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV57804529; called by muse, mutect2, varscan2
- EVI5 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1198192527, COSV64825756; called by muse, mutect2, varscan2
- FAM117B | c.995T>G p.I332S | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV57416886; called by muse, mutect2, varscan2
- FAM214B | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1386396552, COSV59715145; called by muse, mutect2, varscan2
- FAM3A | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1557219271, COSV59194128; called by muse, mutect2, varscan2
- FAM83B | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs753449193, COSV60919807; called by muse, mutect2, varscan2
- FAT1 | c.11431G>A p.E3811K | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs927145331, COSV71672251; called by muse, mutect2, varscan2
- FAT3 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53081920, COSV99963863; called by muse, mutect2, varscan2
- FBLN2 | c.3198G>A p.T1066= | Splice Region (SNP) | VAF 26/40 reads (65%) | catalogued as COSV55480602, COSV55482878; called by muse, mutect2, varscan2
- FBN3 | c.7779C>G p.C2593W | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54454675; called by muse, mutect2, varscan2
- FBXO24 | c.113C>T p.S38F (on ENST00000241071 / NM_033506.3; = p.S76F on NM_012172.5) | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53824138; called by muse, mutect2, varscan2
- FBXO40 | c.938A>C p.H313P | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57522279; called by muse, mutect2, varscan2
- FLT3 | c.2965C>T p.Q989* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as COSV54046010; called by muse, mutect2, varscan2
- FOXN1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); catalogued as COSV56880687; called by muse, mutect2, varscan2
- GABRG1 | c.874T>A p.F292I | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54950629; called by muse, mutect2, varscan2
- GALNT17 | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV61149982; called by muse, mutect2, varscan2
- GCC2 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 81/194 reads (42%) | catalogued as COSV100565390, COSV59179350; called by muse, mutect2, varscan2
- GCC2 | c.1517A>T p.E506V | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100565391; called by muse, mutect2, varscan2
- GCOM1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs768883780, COSV51088418; called by muse, mutect2, varscan2
- GFRAL | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1435960298, COSV61229158; called by muse, mutect2, varscan2
- GIT2 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV58078524; called by muse, mutect2
- GLCCI1 | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.536); catalogued as rs779439674, COSV56200264; called by muse, mutect2, varscan2
- GLRB | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV52413745, COSV52419568; called by muse, mutect2, varscan2
- GNAI3 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV63983314, COSV63983963; called by muse, mutect2, varscan2
- GNL3L | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV60575533; called by muse, mutect2, varscan2
- GPC4 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.476); catalogued as rs962591498, COSV63697027; called by muse, mutect2, varscan2
- GPR141 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 116/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1361986821, COSV57731451, COSV57732721; called by muse, mutect2, varscan2
- GPR142 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as COSV59518739; called by muse, mutect2, varscan2
- GPR149 | c.741A>C p.R247S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV67666045; called by muse, mutect2, varscan2
- GRAMD1B | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59200948; called by muse, mutect2, varscan2
- GRID2 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 119/271 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV56178230; called by muse, mutect2, varscan2
- GRIK1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100516902, COSV100517734, COSV58711969; called by muse, mutect2, varscan2
- GRK7 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53821761; called by muse, mutect2, varscan2
- GSTM1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1259669984, COSV59166526; called by muse, mutect2, varscan2
- GUCY1A2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.97); PolyPhen probably damaging (1); catalogued as COSV56477375; called by muse, mutect2, varscan2
- H1-8 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs767397650, COSV60973478; called by muse, mutect2, varscan2
- H4-16 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); catalogued as COSV63761851; called by muse, mutect2, varscan2
- HCFC1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 104/261 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV60069835; called by muse, mutect2, varscan2
- HECW2 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1220232756, COSV53651211; called by muse, varscan2
- HLA-DMA | c.394T>C p.F132L | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV66385462; called by muse, mutect2, varscan2
- HMOX2 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV54859592; called by muse, mutect2, varscan2
- HSD11B2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 121/319 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs147758873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA4 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59181801; called by muse, mutect2, varscan2
- HSPA4L | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.891); catalogued as COSV56544042; called by muse, mutect2, varscan2
- IFT43 | c.313G>A p.D105N (on ENST00000314067 / NM_001102564.3; = p.D110N on NM_052873.3) | Missense Mutation (SNP) | VAF 304/689 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53137043; called by muse, mutect2, varscan2
- IGF1R | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 117/210 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51271459; called by muse, mutect2, varscan2
- IGSF1 | c.1539G>A p.W513* | Nonsense Mutation (SNP) | VAF 210/472 reads (44%) | catalogued as COSV63836418, COSV63837427; called by muse, mutect2, varscan2
- IKZF2 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430123351, COSV59576842; called by muse, mutect2, varscan2
- IL18RAP | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.066); catalogued as COSV51824189; called by muse, mutect2, varscan2
- IL1R2 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV60205930; called by muse, mutect2, varscan2
- INAVA | c.1313T>C p.F438S | Missense Mutation (SNP) | VAF 399/671 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV66255995; called by muse, mutect2, varscan2
- INF2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53030475; called by muse, mutect2, varscan2
- INPP5D | c.2749G>A p.G917R (on ENST00000445964 / NM_001017915.3; = p.G916R on NM_005541.5) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV64035701; called by muse, mutect2, varscan2
- INSM2 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51877700; called by muse, mutect2, varscan2
- IQCG | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 140/349 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV54560586; called by muse, mutect2, varscan2
- IRS1 | c.2400T>G p.Y800* | Nonsense Mutation (SNP) | VAF 119/287 reads (41%) | catalogued as COSV59334121; called by muse, mutect2, varscan2
- ISOC2 | c.349-6C>T | Splice Region (SNP) | VAF 13/59 reads (22%) | catalogued as rs751246997, COSV50034837; called by muse, mutect2, varscan2
- ITGA3 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.068); catalogued as COSV50306383; called by muse, mutect2, varscan2
- ITPRID1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs751450096, COSV60070821; called by muse, mutect2, varscan2
- JPH2 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV65902005; called by muse, mutect2, varscan2
- KCNH1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55071434; called by muse, mutect2, varscan2
- KCNJ5 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.983); catalogued as rs758781514, COSV57963700; called by muse, mutect2, varscan2
- KCTD5 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV57063763; called by muse, mutect2, varscan2
- KDM8 | c.667T>G p.L223V | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.125); catalogued as COSV53728543; called by muse, mutect2, varscan2
- KIAA1109 | c.6968C>A p.S2323Y | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52664151, COSV52692569; called by muse, mutect2, varscan2
- KIAA1210 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775653483, COSV68175814; called by muse, mutect2, varscan2
- KIF4B | c.1694A>C p.E565A | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV70528124; called by muse, mutect2, varscan2
- KITLG | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 110/245 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV57200202; called by muse, mutect2, varscan2
- KRT1 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 117/274 reads (43%) | catalogued as COSV52865250; called by muse, mutect2, varscan2
- KRT222 | c.226-1G>A p.X76_splice | Splice Site (SNP) | VAF 40/99 reads (40%) | catalogued as COSV67497827; called by muse, mutect2, varscan2
- KRT85 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs778900611, COSV57736125; called by muse, mutect2, varscan2
- KRTAP5-10 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as COSV64794186; called by muse, mutect2, varscan2
- KSR2 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV56667040; called by muse, mutect2, varscan2
- L3MBTL4 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53114708; called by muse, mutect2, varscan2
- LAMA3 | c.9341G>A p.G3114E (on ENST00000313654 / NM_198129.4; = p.G1505E on NM_000227.6) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV52530665; called by muse, mutect2, varscan2
- LEPR | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV62745991; called by muse, mutect2, varscan2
- LILRB4 | c.1169G>A p.R390K (on ENST00000391733 / NM_001278428.3; = p.R389K on NM_001278426.3) | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV54403786; called by muse, mutect2, varscan2
- LIMD1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs776587629, COSV56266074; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.531A>T p.E177D | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV53275950, COSV53286998; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.601A>T p.K201* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as COSV53275964; called by muse, mutect2, varscan2
- LMNTD2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs185418838, COSV54238120; called by mutect2, varscan2
- LMTK3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV54309632, COSV54315717; called by muse, mutect2, varscan2
- LRP1B | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs868335735, COSV67192117; called by muse, mutect2, varscan2
- LRP2 | c.5553C>G p.H1851Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV104379225, COSV55543296; called by muse, mutect2, varscan2
- LRP4 | c.322dup p.R108Pfs*4 | Frame Shift Ins (INS) | VAF 43/145 reads (30%) | catalogued as rs35014453; called by mutect2, pindel, varscan2
- LRRC49 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as rs955435542, COSV51436256, COSV51436675; called by muse, mutect2, varscan2
- LRRIQ4 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1413452358, COSV61618740; called by muse, mutect2, varscan2
- LRRK2 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54145773; called by muse, mutect2, varscan2
- MAGEA1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.338); catalogued as COSV63118289; called by muse, mutect2, varscan2
- MAGEA3 | c.401A>C p.E134A | Missense Mutation (SNP) | VAF 114/319 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64755851; called by muse, mutect2, varscan2
- MAGEC1 | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 138/326 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1177900758, COSV53568991; called by muse, mutect2, varscan2
- MAML3 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 219/579 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59071716; called by muse, mutect2, varscan2
- MARCO | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs773593813, COSV59052284; called by muse, mutect2, varscan2
- MARCO | c.1339T>G p.C447G | Missense Mutation (SNP) | VAF 128/326 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59052296; called by muse, mutect2, varscan2
- MARK1 | c.953A>C p.E318A | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV65065910; called by muse, mutect2, varscan2
- MB21D2 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV66661939; called by muse, mutect2, varscan2
- MCM3 | c.2446T>C p.F816L (on ENST00000229854 / NM_001366374.2; = p.F806L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV57716722; called by muse, mutect2, varscan2
- MCM9 | c.371T>C p.L124S | Missense Mutation (SNP) | VAF 278/354 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60163486; called by muse, mutect2, varscan2
- MDFI | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV57821675; called by muse, mutect2, varscan2
- MGA | c.8582G>A p.R2861Q (on ENST00000219905 / NM_001164273.1; = p.R2652Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs187485107, COSV54949789; called by muse, mutect2, varscan2
- MGAT2 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53565651; called by muse, mutect2, varscan2
- MID2 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99464430; called by muse, mutect2, varscan2
- MLXIP | c.2509T>C p.F837L | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV59834226; called by muse, mutect2, varscan2
- MORN3 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1555325475, COSV62507093; called by muse, mutect2, varscan2
- MPP1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.928); catalogued as COSV65728041; called by muse, mutect2, varscan2
- MRC2 | c.230G>A p.W77* | Nonsense Mutation (SNP) | VAF 67/151 reads (44%) | catalogued as COSV57637242; called by muse, mutect2, varscan2
- MROH5 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 98/191 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV71300580; called by muse, mutect2
- MROH8 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as rs1328296896, COSV54117780; called by muse, mutect2, varscan2
- MTUS2 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.548); catalogued as rs1338353403, COSV70914200; called by muse, mutect2, varscan2
- MTUS2 | c.3763G>A p.E1255K (on ENST00000612955 / NM_001366650.1; = p.E234K on NM_015233.6) | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs371216693; called by muse, mutect2, varscan2
- MUC16 | c.40354C>T p.P13452S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV66690239; called by muse, mutect2, varscan2
- MUC16 | c.29864C>T p.T9955I | Missense Mutation (SNP) | VAF 187/489 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV67449074, COSV67465843, COSV67502802; called by muse, mutect2, varscan2
- MUC16 | c.15410C>T p.S5137F | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.13); catalogued as COSV67449081; called by muse, mutect2, varscan2
- MUC16 | c.12072G>A p.M4024I | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.138); catalogued as rs1467795178, COSV67449094; called by muse, mutect2, varscan2
- MUC16 | c.10559C>T p.S3520L | Missense Mutation (SNP) | VAF 116/328 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV67449114; called by muse, varscan2
- MYH1 | c.4775G>A p.R1592K | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs1457247111, COSV56844482, COSV56848529; called by muse, mutect2, varscan2
- MYH15 | c.5454G>A p.M1818I | Missense Mutation (SNP) | VAF 107/316 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV56305301; called by muse, mutect2, varscan2
- MYH15 | c.5309C>T p.A1770V | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV56305314; called by muse, mutect2, varscan2
- MYH15 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs370509544, COSV56305326; called by muse, mutect2, varscan2
- MYH6 | c.3116C>T p.S1039F | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1398042911, COSV62448284, COSV62449858; called by muse, mutect2, varscan2
- MYH8 | c.4962G>A p.K1654= | Splice Region (SNP) | VAF 165/399 reads (41%) | catalogued as COSV67960796, COSV67973024; called by muse, mutect2, varscan2
- MYH8 | c.4324T>G p.C1442G | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV67960800; called by muse, mutect2, varscan2
- MYH8 | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 243/587 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV67960805; called by muse, mutect2, varscan2
- MYO18B | c.6478G>A p.E2160K | Missense Mutation (SNP) | VAF 327/371 reads (88%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs371851187; called by muse, mutect2, varscan2
- NAA30 | c.979A>T p.K327* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as COSV53648146; called by muse, mutect2, varscan2
- NALCN | c.3571C>T p.P1191S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV51921052; called by muse, mutect2, varscan2
- NANOS2 | c.263T>G p.V88G | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58024796; called by muse, mutect2, varscan2
- NCAM1 | c.2105C>T p.T702I (on ENST00000316851 / NM_181351.5; = p.T692I on NM_000615.7) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1183871302, COSV100377479; called by muse, mutect2, varscan2
- NCEH1 | c.667G>A p.G223S (on ENST00000538775; = p.G183S on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56433040; called by muse, mutect2, varscan2
- NCKAP5L | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60127835; called by muse, mutect2, varscan2
- NDOR1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV61286690; called by muse, mutect2, varscan2
- NDST3 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56613849; called by muse, mutect2, varscan2
- NEBL | c.1228-1G>A p.X410_splice | Splice Site (SNP) | VAF 15/27 reads (56%) | catalogued as COSV65801622; called by muse, mutect2, varscan2
- NEBL | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as COSV65801626; called by muse, mutect2, varscan2
- NEBL | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472235973, COSV65799507, COSV65799803; called by muse, mutect2, varscan2
- NEDD1 | c.1228T>C p.F410L | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV57141815; called by muse, mutect2, varscan2
- NEXMIF | c.4391G>A p.G1464E | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs764469950, COSV50022654; called by muse, mutect2, varscan2
- NEXN | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV53927093; called by muse, mutect2, varscan2
- NHS | c.2177G>A p.S726N | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV66272014; called by muse, mutect2, varscan2
- NIN | c.4834C>G p.Q1612E (on ENST00000382041 / NM_182946.1; = p.Q899E on NM_016350.4) | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55381882; called by muse, mutect2
- NLRP1 | c.1610A>T p.K537M | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV52559657; called by muse, mutect2, varscan2
- NLRP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708963; called by muse, mutect2, varscan2
- NLRP7 | c.2593T>A p.F865I (on ENST00000340844 / NM_206828.3; = p.F837I on NM_139176.3) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV60171630; called by muse, mutect2, varscan2
- NLRP8 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV52583255; called by muse, mutect2, varscan2
- NOMO1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 150/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55057282; called by muse, mutect2, varscan2
- NOMO1 | c.1157T>C p.F386S | Missense Mutation (SNP) | VAF 108/415 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV55057303; called by muse, mutect2, varscan2
- NOP58 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 64/188 reads (34%) | catalogued as COSV51895749; called by muse, mutect2, varscan2
- NOX5 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs935376693, COSV52985550; called by muse, mutect2, varscan2
- NPAP1 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.188); catalogued as COSV61504997; called by muse, mutect2, varscan2
- NPHP4 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374373238; called by muse, mutect2, varscan2
- NSRP1 | c.774T>G p.D258E | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV55933079; called by muse, mutect2, varscan2
- NUP210L | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 224/561 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs182423356, COSV55142064; called by muse, mutect2, varscan2
- NYNRIN | c.2077A>G p.T693A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV66841350; called by muse, mutect2, varscan2
- OBSCN | c.10573G>A p.E3525K | Missense Mutation (SNP) | VAF 173/322 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV52747190; called by muse, mutect2, varscan2
- OGT | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65479738; called by muse, mutect2, varscan2
- OR11H4 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 181/486 reads (37%) | catalogued as COSV59559887; called by muse, mutect2, varscan2
- OR13A1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs768391067, COSV65572024; called by muse, mutect2, varscan2
- OR14A16 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 264/441 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs201678616, COSV62926201; called by muse, mutect2, varscan2
- OR1J2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs372492437, COSV58944775; called by muse, mutect2, varscan2
- OR1L8 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs771093917, COSV59185779; called by muse, mutect2
- OR2T11 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs564273793, COSV58184856; called by muse, mutect2, varscan2
- OR2T34 | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as rs374601859; called by muse, varscan2
- OR4C15 | c.523C>T p.R175C (on ENST00000314644; = p.R121C on NM_001001920.2) | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- OR4C6 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); catalogued as COSV58602760; called by muse, mutect2, varscan2
- OR4D1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV52124627; called by muse, mutect2, varscan2
- OR4D9 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV61434165; called by muse, mutect2, varscan2
- OR51B2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1299360359, COSV60916055, COSV60917267; called by muse, mutect2, varscan2
- OR51B5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs1441314371, COSV56175085; called by muse, mutect2, varscan2
- OR52B2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV73209242; called by muse, mutect2, varscan2
- OR52E2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as COSV58611954; called by muse, mutect2, varscan2
- OR6C4 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.097); catalogued as COSV67792781; called by muse, mutect2, varscan2
- OR6C4 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as COSV67792784; called by muse, mutect2, varscan2
- OR6T1 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs76969055, COSV58305873, COSV58308619; called by muse, mutect2, varscan2
- OR7A5 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 59/134 reads (44%) | catalogued as rs374657730; called by muse, mutect2, varscan2
- OR8H1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 185/509 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs867315106, COSV57293250; called by muse, mutect2, varscan2
- OR8H2 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 110/396 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV57943427; called by mutect2, varscan2
- OR8H3 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 143/328 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV57907597; called by muse, varscan2
- OR8H3 | c.319T>A p.L107M | Missense Mutation (SNP) | VAF 294/608 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV100539173, COSV57907629; called by muse, mutect2, varscan2
- OTUD7B | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); catalogued as COSV64915320; called by muse, mutect2, varscan2
- PACS2 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV57650406; called by muse, mutect2, varscan2
- PADI6 | c.1492A>C p.K498Q | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV61883829; called by muse, mutect2, varscan2
- PAK5 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 134/330 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.622); catalogued as COSV62022283; called by muse, mutect2, varscan2
- PAMR1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs139194536; called by muse, mutect2, varscan2
- PANK1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs1224194872, COSV56806600; called by muse, mutect2, varscan2
- PARP14 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV71734199; called by muse, mutect2, varscan2
- PAXBP1 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 53/132 reads (40%) | catalogued as COSV51606893, COSV51607146; called by muse, mutect2, varscan2
- PC | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV63079234; called by muse, mutect2, varscan2
- PCDH18 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 156/420 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV61266399; called by muse, mutect2, varscan2
- PCDHB5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as COSV50647190; called by muse, mutect2, varscan2
- PCDHB7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs546236115, COSV50755630; called by muse, mutect2, varscan2
- PCDHGA10 | c.1117T>A p.L373I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.26); catalogued as COSV53908002; called by muse, mutect2, varscan2
- PCDHGA2 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.02); catalogued as COSV53907972; called by muse, mutect2, varscan2
- PCDHGA8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53907990; called by muse, mutect2, varscan2
- PCDHGC3 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52745136; called by muse, mutect2, varscan2
- PCLO | c.12131G>A p.R4044Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271626427, COSV61619046; called by muse, mutect2, varscan2
- PCLO | c.4462C>T p.P1488S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61619060; called by muse, mutect2, varscan2
- PCNT | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV64025639, COSV64031310; called by muse, mutect2, varscan2
- PCNX4 | c.2923G>A p.V975I (on ENST00000406854 / NM_001330177.2; = p.V741I on NM_022495.5) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs1403715437, COSV58302605, COSV58305408; called by muse, mutect2, varscan2
- PDE1B | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 119/314 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.157); catalogued as COSV54490023; called by muse, mutect2, varscan2
- PDZD2 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs745533891, COSV56852300; called by muse, mutect2, varscan2
- PDZD4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV51245472; called by muse, mutect2, varscan2
- PEG3 | c.4495C>T p.Q1499* | Nonsense Mutation (SNP) | VAF 94/241 reads (39%) | catalogued as COSV55626738; called by muse, mutect2, varscan2
- PGAP1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs1429621067, COSV61324246; called by muse, mutect2, varscan2
- PHKA1 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59802379; called by muse, mutect2, varscan2
- PHLPP2 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.548); catalogued as rs761074922, COSV62422826; called by muse, mutect2, varscan2
- PIBF1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV58320690; called by muse, mutect2, varscan2
- PIK3CG | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as rs1383854511, COSV63246020; called by muse, mutect2, varscan2
- PIM2 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs1471396715, COSV55943954, COSV99900410; called by muse, mutect2, varscan2
- PKHD1L1 | c.8149G>A p.G2717R | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV65738531; called by muse, mutect2, varscan2
- PLAGL1 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV99394313; called by muse, mutect2, varscan2
- PLAUR | c.1000T>G p.W334G | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV55388795; called by muse, mutect2, varscan2
- PLCG2 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.423); catalogued as rs996161733, COSV63867768; called by muse, mutect2, varscan2
- PLD5 | c.1106A>G p.E369G (on ENST00000442594; = p.E307G on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV59135393; called by muse, mutect2, varscan2
- PLEKHA3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV52293272; called by muse, mutect2, varscan2
- PLEKHH1 | c.3136G>A p.D1046N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs762359584, COSV61280881; called by muse, mutect2, varscan2
- PLXNA4 | c.3324G>C p.Q1108H | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV58108399; called by muse, mutect2, varscan2
- PMFBP1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs770063636, COSV52821228; called by muse, mutect2, varscan2
- PODXL | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59868825; called by muse, mutect2, varscan2
- POM121L12 | c.847T>G p.F283V | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.348); catalogued as COSV101374911, COSV68692373; called by muse, mutect2, varscan2
- POU6F2 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as COSV101302601; called by muse, varscan2
- PPP2R5B | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51209801; called by muse, mutect2, varscan2
- PPP4R3B | c.2326T>A p.F776I (on ENST00000616407 / NM_001122964.3; = p.F691I on NM_020463.4) | Missense Mutation (SNP) | VAF 121/272 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.41); catalogued as COSV55402196; called by muse, mutect2, varscan2
- PRAMEF2 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs181155957, COSV53572920; called by muse, mutect2, varscan2
- PRB2 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 292/820 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as COSV66982358; called by muse, varscan2
- PREX2 | c.3596-1G>A p.X1199_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55754178; called by muse, mutect2, varscan2
- PRKDC | c.4784C>T p.A1595V | Missense Mutation (SNP) | VAF 166/247 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58045056; called by muse, mutect2, varscan2
- PROX1 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 138/215 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54776401; called by muse, mutect2, varscan2
- PRPS1L1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV72649829; called by muse, mutect2, varscan2
- PRR12 | c.1540C>T p.P514S (on ENST00000615927; = p.P1335S on NM_020719.3) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV69816701; called by muse, mutect2, varscan2
- PRRT2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1319381076, COSV54881676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS35 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as rs574996749, COSV63800188; called by muse, mutect2, varscan2
- PRSS54 | c.1124T>G p.L375W | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54685237, COSV54685699; called by muse, mutect2, varscan2
- PSD | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV50042227; called by muse, mutect2, varscan2
- PTGFR | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66114480; called by muse, mutect2, varscan2
- PTGIS | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.062); catalogued as COSV54835517; called by muse, mutect2, varscan2
- PTH2R | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs373798724, COSV55914177; called by muse, mutect2, varscan2
- PTHLH | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 114/284 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV52366766; called by muse, mutect2, varscan2
- PTPN9 | c.736T>C p.W246R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60722738; called by muse, mutect2, varscan2
- PTPRD | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV61927882, COSV61931443; called by muse, mutect2, varscan2
- PTPRN2 | c.1768C>T p.L590F | Missense Mutation (SNP) | VAF 193/501 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101235335, COSV67025012; called by muse, mutect2, varscan2
- PTPRT | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV61958362; called by muse, mutect2, varscan2
- PTPRZ1 | c.5410C>G p.L1804V | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV66431519; called by muse, mutect2, varscan2
- PUS10 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57450794; called by muse, mutect2, varscan2
- PWWP3B | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61798524; called by muse, mutect2, varscan2
- R3HDM2 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 158/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61285569; called by muse, mutect2, varscan2
- RACGAP1 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56698655; called by muse, mutect2, varscan2
- RACK1 | c.664A>G p.N222D | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV59317673; called by muse, mutect2, varscan2
- RAI2 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.548); catalogued as COSV58963295; called by muse, mutect2, varscan2
- RASAL1 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs767981036, COSV55654133; called by muse, mutect2, varscan2
- RASGEF1C | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV63178018; called by muse, varscan2
- RBM22 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV52270548, COSV52270650; called by muse, mutect2, varscan2
- RBMS1 | c.727C>G p.P243A | Missense Mutation (SNP) | VAF 137/331 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745875781, COSV62350903; called by muse, mutect2, varscan2
- REG1A | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV52068829; called by muse, mutect2, varscan2
- RESF1 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV57020018; called by mutect2, varscan2
- RFX4 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63503209; called by muse, mutect2, varscan2
- RGS16 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751809182, COSV62375511; called by muse, mutect2, varscan2
- RIMBP2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs1232633444, COSV55466326, COSV99900903; called by muse, mutect2, varscan2
- RLIM | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.493); catalogued as COSV60325468; called by muse, mutect2, varscan2
- RNF10 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV58043816; called by muse, mutect2, varscan2
- RNF103 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 222/532 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52893862; called by muse, mutect2, varscan2
- ROBO2 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV100168862, COSV59899442; called by muse, mutect2, varscan2
- RPGRIP1 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV52846016; called by muse, mutect2
- RPL39 | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV64294009; called by muse, mutect2, varscan2
- RPS6KA3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65387046; called by muse, mutect2, varscan2
- RTL3 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV58183371; called by muse, varscan2
- RXFP2 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV53633501, COSV53635751; called by muse, mutect2, varscan2
- RYR3 | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.288); catalogued as COSV66777881, COSV66779954; called by muse, mutect2, varscan2
- SAMD9 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV66073305; called by muse, mutect2, varscan2
- SAMD9L | c.4148C>T p.S1383F | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774340297, COSV59079624; called by muse, mutect2, varscan2
- SCG2 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs368049148; called by muse, varscan2
- SCG2 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 60/141 reads (43%) | catalogued as COSV59539215; called by muse, varscan2
- SCN1A | c.2672G>A p.G891E (on ENST00000303395 / NM_001202435.3; = p.G880E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868742933, COSV57662402; called by muse, mutect2, varscan2
- SCN5A | c.5553G>A p.M1851I (on ENST00000333535 / NM_198056.3; = p.M1850I on NM_000335.5) | Missense Mutation (SNP) | VAF 79/98 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs1201716451, COSV61117691; called by muse, mutect2, varscan2
- SCUBE2 | c.2378C>G p.T793S (on ENST00000649792 / NM_001367977.2; = p.T736S on NM_020974.3) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV58540930; called by muse, mutect2, varscan2
- SCUBE3 | c.388A>C p.M130L | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.448); catalogued as COSV51455218; called by muse, mutect2, varscan2
- SDAD1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs754724162, COSV62402389; called by muse, mutect2, varscan2
- SEMA4A | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as COSV61772175; called by muse, mutect2, varscan2
- SEMG2 | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65647253; called by muse, mutect2, varscan2
- SERPINI2 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52984611; called by muse, mutect2, varscan2
- SFTPC | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV59345288; called by muse, varscan2
- SH2D4A | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1037619266, COSV56121459; called by muse, mutect2, varscan2
- SH3RF2 | c.1097A>C p.H366P | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV63037501; called by muse, mutect2, varscan2
- SHKBP1 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 140/354 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52537951; called by muse, mutect2, varscan2
- SHPRH | c.2851A>G p.K951E | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51605449; called by muse, mutect2, varscan2
- SHPRH | c.2665C>T p.P889S | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV51605473; called by muse, mutect2, varscan2
- SHROOM4 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as rs782476625, COSV56785313; called by muse, mutect2, varscan2
- SIDT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs376848215; called by muse, mutect2, varscan2
- SIGLECL1 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 157/309 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57062223; called by muse, mutect2, varscan2
- SLC10A3 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54835673; called by muse, mutect2
- SLC14A1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.104); catalogued as rs868527298, COSV58930983; called by muse, mutect2, varscan2
- SLC1A2 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV53519083; called by muse, mutect2
- SLC1A3 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 85/204 reads (42%) | catalogued as COSV54314420; called by muse, mutect2, varscan2
- SLC1A6 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV55668403; called by muse, mutect2, varscan2
- SLC25A45 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV53683365; called by muse, mutect2, varscan2
- SLC27A2 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV51057717; called by muse, mutect2, varscan2
- SLC2A6 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV64141870; called by muse, mutect2, varscan2
- SLC30A10 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 198/322 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs749768848, COSV63070542; called by muse, mutect2, varscan2
- SLC30A4 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 80/154 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs745899103, COSV56005232; called by muse, mutect2, varscan2
- SLC35F4 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100333739; called by muse, mutect2, varscan2
- SLC39A7 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV63399504; called by muse, mutect2, varscan2
- SLC4A1 | c.2183C>T p.T728I | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99293248; called by muse, mutect2, varscan2
- SLC4A3 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as rs549219468, COSV56091935; called by muse, mutect2, varscan2
- SLC7A2 | c.1379C>T p.S460L (on ENST00000494857 / NM_001370338.1; = p.S499L on NM_003046.6) | Missense Mutation (SNP) | VAF 70/88 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs754454858, COSV50248168; called by muse, mutect2, varscan2
- SLC8A1 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs760569632, COSV60472601; called by muse, varscan2
- SLC8A3 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as COSV53687876, COSV99385369; called by muse, mutect2, varscan2
- SLC8A3 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as COSV63519384; called by muse, mutect2, varscan2
- SLC9A4 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54828502; called by muse, mutect2, varscan2
- SLC9A8 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs375209126; called by muse, mutect2, varscan2
- SLITRK6 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV68389510, COSV68390569; called by muse, mutect2, varscan2
- SMARCA1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs964072317, COSV64411036; called by muse, mutect2, varscan2
- SMARCC2 | c.3505C>T p.Q1169* | Nonsense Mutation (SNP) | VAF 94/214 reads (44%) | catalogued as COSV53237469; called by muse, mutect2, varscan2
- SMYD5 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 107/250 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV50264430; called by muse, mutect2, varscan2
- SORCS3 | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.25); PolyPhen benign (0.263); catalogued as COSV63793647; called by muse, mutect2, varscan2
- SP140 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59446871; called by muse, mutect2, varscan2
- SPATA16 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 168/448 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); catalogued as rs781047974, COSV63527108; called by muse, mutect2, varscan2
- SPATA20 | c.2171C>T p.S724F (on ENST00000356488 / NM_001258372.1; = p.S740F on NM_022827.4) | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs1178030666, COSV50065902; called by muse, mutect2, varscan2
- SPIN3 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 151/362 reads (42%) | catalogued as COSV66529005; called by muse, mutect2, varscan2
- SPOCK3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.091); catalogued as rs1422436706, COSV62718113; called by muse, mutect2, varscan2
- SPTA1 | c.5957C>T p.P1986L | Missense Mutation (SNP) | VAF 354/890 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1237552137, COSV63749716; called by muse, mutect2, varscan2
- SPTB | c.6121G>A p.V2041M | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs776954379, COSV61551933; called by muse, mutect2, varscan2
- SPTB | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs267604024, COSV67630198; called by muse, mutect2, varscan2
- SPTBN2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as rs372390933, COSV59447885; called by muse, mutect2, varscan2
- SPTLC3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV65463988; called by muse, mutect2, varscan2
- SSTR4 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 116/299 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as rs1319886412, COSV54797212; called by muse, mutect2, varscan2
- ST14 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53831716; called by muse, varscan2
- ST18 | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52486094; called by muse, mutect2, varscan2
- STAT6 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV55669414; called by muse, mutect2, varscan2
- STON2 | c.977C>T p.S326L (on ENST00000649389 / NM_001366849.2; = p.S269L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.012); catalogued as COSV50842623; called by muse, mutect2, varscan2
- STRN | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as COSV55746330; called by muse, mutect2, varscan2
- STS | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV54266382; called by muse, mutect2, varscan2
- STXBP5L | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1022469648, COSV56502396; called by muse, mutect2, varscan2
- SULT1C2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139416622; called by muse, mutect2, varscan2
- SULT1C4 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs137946991; called by muse, mutect2, varscan2
- SYCP1 | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 47/123 reads (38%) | catalogued as COSV65694949; called by muse, mutect2, varscan2
- SYNE1 | c.1306G>A p.E436K (on ENST00000367255 / NM_182961.4; = p.E443K on NM_033071.3) | Missense Mutation (SNP) | VAF 143/191 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs373901808; called by muse, mutect2, varscan2
- SYNM | c.2210G>A p.R737K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as COSV60368174; called by muse, mutect2, varscan2
- SYT14 | c.1518T>A p.Y506* | Nonsense Mutation (SNP) | VAF 92/331 reads (28%) | catalogued as COSV55049765; called by muse, mutect2, varscan2
- TAAR8 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 67/76 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV51585690; called by muse, mutect2, varscan2
- TACR3 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs199740086, COSV59197645; called by muse, mutect2, varscan2
- TAF7L | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 323/750 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.026); catalogued as COSV63299417; called by muse, mutect2, varscan2
- TCL1A | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1368717676, COSV68085134; called by muse, varscan2
- TCL1A | c.121-1G>A p.X41_splice | Splice Site (SNP) | VAF 38/74 reads (51%) | catalogued as rs1166035293, COSV68085138; called by muse, varscan2
- TDRKH | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64316040; called by muse, mutect2, varscan2
- TECTA | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV50690167; called by muse, mutect2, varscan2
- TENM3 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 88/227 reads (39%) | catalogued as COSV69300309; called by muse, mutect2, varscan2
- TEX15 | c.3564A>T p.E1188D (on ENST00000256246; = p.E1571D on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV56342546; called by muse, mutect2, varscan2
- TG | c.7694C>T p.S2565F | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55066884; called by muse, mutect2, varscan2
- TGFB1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55724018; called by muse, mutect2, varscan2
- TGFB3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV53169022; called by muse, mutect2, varscan2
- THPO | c.1196G>A p.G399E (on ENST00000649095 / NM_001290003.1; = p.G259E on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52614923; called by muse, varscan2
- THPO | c.1195G>A p.G399R (on ENST00000649095 / NM_001290003.1; = p.G259R on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99201184; called by muse, mutect2, varscan2
- TIAM1 | c.3994C>T p.R1332* | Nonsense Mutation (SNP) | VAF 156/385 reads (41%) | catalogued as COSV54539924; called by muse, mutect2, varscan2
- TLL1 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 181/437 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV50263197; called by muse, mutect2, varscan2
- TLL1 | c.2191A>G p.K731E | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV50263204; called by muse, mutect2, varscan2
- TMEM132B | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100169277, COSV100169916; called by muse, mutect2, varscan2
- TMEM132B | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs1314377715, COSV100170513, COSV54753966; called by muse, mutect2, varscan2
- TMEM200A | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.96); catalogued as rs768461562, COSV51649931; called by muse, mutect2, varscan2
- TMPRSS3 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 173/459 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.326); catalogued as COSV52300415; called by muse, mutect2, varscan2
- TNFRSF1B | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs866383062, COSV66163568; called by muse, mutect2, varscan2
- TNFRSF21 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV57280436; called by muse, mutect2, varscan2
- TNFSF10 | c.189T>G p.S63R | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53842587; called by muse, mutect2, varscan2
- TNS1 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as rs1258214177, COSV50692136; called by muse, mutect2, varscan2
- TRHDE | c.1730G>A p.R577K | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1451611636, COSV53835051, COSV99668350; called by muse, mutect2, varscan2
- TRIM10 | c.929-1G>A p.X310_splice | Splice Site (SNP) | VAF 45/170 reads (26%) | catalogued as COSV65000781; called by muse, mutect2, varscan2
- TRMT1L | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV62271763; called by muse, mutect2, varscan2
- TRPC4 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58991999; called by muse, mutect2, varscan2
- TRPC6 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 137/306 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60251396; called by muse, mutect2, varscan2
- TSHZ2 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61587213; called by muse, mutect2, varscan2
- TSPOAP1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52104641; called by muse, mutect2, varscan2
- TSSK1B | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1337335706, COSV66814950; called by muse, mutect2, varscan2
- TTC7A | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV55408774; called by muse, mutect2, varscan2
- TTLL6 | c.2351G>A p.G784E (on ENST00000393382 / NM_001130918.3; = p.G477E on NM_173623.3) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64976398; called by muse, mutect2, varscan2
- TTN | c.71962G>A p.G23988R (on ENST00000591111; = p.G16564R on NM_003319.4) | Missense Mutation (SNP) | VAF 133/355 reads (37%) | PolyPhen probably damaging (1); catalogued as COSV59913057; called by muse, mutect2, varscan2
- TTN | c.65245A>G p.N21749D (on ENST00000591111; = p.N14325D on NM_003319.4) | Missense Mutation (SNP) | VAF 113/282 reads (40%) | PolyPhen benign (0.085); catalogued as COSV59913080; called by muse, mutect2, varscan2
- TTN | c.61615C>G p.P20539A (on ENST00000591111; = p.P13115A on NM_003319.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | PolyPhen probably damaging (0.997); catalogued as rs1243610745, COSV59913106; called by muse, mutect2, varscan2
- TTN | c.8231G>A p.G2744E (on ENST00000591111; = p.G2698E on NM_003319.4) | Missense Mutation (SNP) | VAF 110/258 reads (43%) | PolyPhen probably damaging (1); catalogued as COSV59913155; called by muse, mutect2, varscan2
- TULP2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV55476949; called by muse, mutect2, varscan2
- TYRO3 | c.1652T>G p.M551R | Missense Mutation (SNP) | VAF 118/240 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV55481206; called by muse, mutect2, varscan2
- UBQLNL | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV66492746; called by muse, mutect2, varscan2
- UBR4 | c.2852T>C p.V951A | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV64383629; called by muse, mutect2, varscan2
- UGT2B15 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 71/400 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV57733208; called by muse, mutect2, varscan2
- UGT2B17 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV58500964; called by muse, mutect2, varscan2
- UNC13A | c.4763A>C p.K1588T | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53189623; called by muse, mutect2, varscan2
- USO1 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV53705401; called by muse, mutect2, varscan2
- USP15 | c.1760C>A p.S587* (on ENST00000280377 / NM_001351159.2; = p.S558* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 47/107 reads (44%) | catalogued as COSV54788596; called by muse, mutect2, varscan2
- USP43 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV53300203; called by muse, mutect2, varscan2
- USP9X | c.2876C>T p.S959L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61066586; called by muse, mutect2, varscan2
- VANGL2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751810965, COSV63604084, COSV63605123; called by muse, mutect2, varscan2
- VAT1L | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.523); catalogued as COSV56815237; called by muse, varscan2
- VCAM1 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761247461, COSV54118036; called by muse, mutect2, varscan2
- VEPH1 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62876430; called by muse, mutect2, varscan2
- VNN2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1409733371, COSV58471553; called by muse, mutect2, varscan2
- VPREB1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 113/132 reads (86%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV56425395; called by muse, mutect2, varscan2
- VPS36 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65198711; called by muse, mutect2, varscan2
- VPS52 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV71403408; called by muse, mutect2, varscan2
- WNT8B | c.568A>C p.T190P | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59324682; called by muse, mutect2, varscan2
- XIRP2 | c.3220G>A p.D1074N (on ENST00000628543; = p.D1249N on NM_152381.6) | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54685657; called by muse, mutect2, varscan2
- XIRP2 | c.9163C>T p.R3055C (on ENST00000628543; = p.R3230C on NM_152381.6) | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV54685665; called by muse, mutect2, varscan2
- ZC3H6 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59666239; called by muse, mutect2, varscan2
- ZFHX3 | c.7940C>T p.T2647I | Missense Mutation (SNP) | VAF 248/592 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51710459, COSV51733200; called by muse, mutect2, varscan2
- ZFHX4 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866599341, COSV50512080, COSV51476340; called by muse, mutect2, varscan2
- ZIC3 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54972532; called by muse, varscan2
- ZIC3 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs1301039896, COSV54972550; called by muse, varscan2
- ZNF112 | c.2393T>C p.V798A (on ENST00000337401 / NM_001083335.2; = p.V792A on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV61619018; called by muse, mutect2, varscan2
- ZNF280C | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV63968593; called by muse, mutect2, varscan2
- ZNF311 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV65852900; called by muse, mutect2, varscan2
- ZNF33A | c.310G>A p.E104K (on ENST00000458705 / NM_006974.3; = p.E105K on NM_006954.2) | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV56723538; called by muse, mutect2, varscan2
- ZNF385B | c.142T>A p.F48I | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV69801030; called by muse, mutect2, varscan2
- ZNF410 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV57910049; called by muse, mutect2, varscan2
- ZNF438 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV59192682; called by muse, mutect2, varscan2
- ZNF528 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64618253; called by muse, mutect2, varscan2
- ZNF534 | c.913C>T p.H305Y (on ENST00000332323 / NM_001143939.3; = p.H292Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs267605633, COSV56514865; called by muse, mutect2, varscan2
- ZNF536 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 141/377 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62819567; called by muse, mutect2, varscan2
- ZNF646 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 32/63 reads (51%) | catalogued as COSV54922922; called by muse, mutect2, varscan2
- ZNF667 | c.164T>A p.L55H | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV52631709; called by muse, mutect2, varscan2
- ZNF668 | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 85/191 reads (45%) | catalogued as COSV56211817; called by muse, mutect2, varscan2
- ZNF780A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs779290425, COSV61814680; called by muse, mutect2, varscan2
- ZPBP | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV50422820; called by muse, mutect2, varscan2
- CDC42BPA | c.2085_2102del p.K696_E701del | In Frame Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- CT45A1 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 132/1308 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DNAJA3 | c.82del p.R28Gfs*12 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- GTF2H2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- IGHV1OR21-1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 21/368 reads (6%) | called by muse, mutect2
- IGKV3D-20 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- IGKV5-2 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KPNB1 | c.2222del p.Q741Rfs*18 | Frame Shift Del (DEL) | VAF 75/202 reads (37%) | called by mutect2, pindel, varscan2
- LGALS1 | c.224dup p.A76Gfs*49 | Frame Shift Ins (INS) | VAF 29/43 reads (67%) | called by mutect2, pindel, varscan2
- MYT1L | c.1855del p.Y619Tfs*41 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- OR8G2P | c.182A>C p.Y61S | Missense Mutation (SNP) | VAF 132/331 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PRKCZ | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SVEP1 | c.4499del p.T1500Kfs*6 | Frame Shift Del (DEL) | VAF 24/45 reads (53%) | called by mutect2, pindel, varscan2
- ABCC8 | c.606G>A p.R202= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as COSV56846987; called by muse, mutect2, varscan2
- ABL2 | c.3042C>T p.S1014= (on ENST00000502732 / NM_007314.4; = p.S999= on NM_005158.5) | Silent (SNP) | VAF 96/217 reads (44%) | catalogued as COSV61011498; called by muse, mutect2, varscan2
- ACACA | c.6150G>A p.Q2050= | Silent (SNP) | VAF 114/235 reads (49%) | catalogued as rs1479085458; called by muse, mutect2, varscan2
- ADAMTS20 | c.2556C>T p.P852= | Silent (SNP) | VAF 74/182 reads (41%) | catalogued as COSV67127738; called by muse, mutect2, varscan2
- ADAR | c.3120C>T p.I1040= | Silent (SNP) | VAF 90/187 reads (48%) | catalogued as rs771995348, COSV52712679; called by muse, mutect2, varscan2
- ADCY1 | c.2766C>T p.I922= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as rs562337987, COSV52030919; called by muse, mutect2, varscan2
- ADGRG7 | c.373C>T p.L125= | Silent (SNP) | VAF 63/123 reads (51%) | catalogued as COSV56294124, COSV56300470; called by muse, mutect2, varscan2
- AFAP1 | c.1875G>A p.K625= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100631504, COSV61793694; called by muse, mutect2, varscan2
- ANK1 | c.4878G>A p.V1626= | Silent (SNP) | VAF 204/254 reads (80%) | catalogued as COSV55874779; called by muse, mutect2, varscan2
- ANKRD35 | c.726G>A p.L242= | Silent (SNP) | VAF 68/145 reads (47%) | catalogued as COSV62909673; called by muse, mutect2, varscan2
- APOA4 | c.1077G>A p.K359= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV63360078; called by muse, mutect2, varscan2
- ARHGAP28 | c.633C>T p.S211= (on ENST00000383472 / NM_001366230.1; = p.S52= on NM_001010000.3) | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV51632439; called by muse, mutect2, varscan2
- ARMC5 | c.183C>T p.F61= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV51655046; called by muse, mutect2, varscan2
- ARSH | c.789C>T p.L263= | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as COSV66962613; called by muse, mutect2, varscan2
- ASIC2 | c.1116G>A p.E372= | Silent (SNP) | VAF 100/226 reads (44%) | catalogued as COSV56756700; called by muse, mutect2, varscan2
- ASXL3 | c.5257T>C p.L1753= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV52458920; called by muse, mutect2, varscan2
- ASXL3 | c.5628A>G p.Q1876= | Silent (SNP) | VAF 204/451 reads (45%) | catalogued as COSV52458934; called by muse, mutect2, varscan2
- ATP10A | c.600G>A p.L200= | Silent (SNP) | VAF 86/197 reads (44%) | catalogued as COSV63514259; called by muse, mutect2, varscan2
- ATP13A5 | c.2517G>A p.Q839= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as COSV60866420; called by muse, mutect2, varscan2
- ATP7A | c.3900A>C p.G1300= | Silent (SNP) | VAF 174/459 reads (38%) | catalogued as COSV58443323; called by muse, mutect2, varscan2
- BMP5 | c.385T>C p.L129= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as COSV63701350; called by muse, mutect2, varscan2
- BOD1L1 | c.3789A>G p.E1263= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs766170896, COSV50007224; called by muse, mutect2, varscan2
- BPHL | c.546T>A p.V182= | Silent (SNP) | VAF 115/374 reads (31%) | catalogued as COSV66743074; called by muse, mutect2, varscan2
- BRPF3 | c.270C>T p.S90= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as COSV60206253; called by muse, mutect2, varscan2
- BTNL9 | c.1527G>A p.G509= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV59793852; called by muse, mutect2
- C3 | c.3279C>T p.I1093= | Silent (SNP) | VAF 130/299 reads (43%) | catalogued as rs201084516, COSV55569653; called by muse, mutect2, varscan2
- C9orf131 | c.2268G>A p.G756= | Silent (SNP) | VAF 69/104 reads (66%) | catalogued as COSV100398036; called by muse, mutect2, varscan2
- CACNA1E | c.2049C>T p.F683= | Silent (SNP) | VAF 123/333 reads (37%) | catalogued as COSV62384035, COSV62387912; called by muse, mutect2, varscan2
- CACNA2D3 | c.429G>A p.G143= | Silent (SNP) | VAF 81/109 reads (74%) | catalogued as rs267599904, COSV55518510; called by muse, mutect2, varscan2
- CALML5 | c.208C>T p.L70= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV100981230, COSV66702384; called by muse, mutect2, varscan2
- CAPN15 | c.2730C>T p.A910= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs564719894, COSV99562372; called by muse, varscan2
- CASQ1 | c.228G>A p.E76= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV63623930, COSV63624131; called by muse, mutect2, varscan2
- CASR | c.960C>T p.F320= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs753011255, COSV56133741; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC22 | c.705C>T p.L235= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV66109171; called by muse, mutect2, varscan2
- CCDC63 | c.1407G>A p.V469= | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as COSV57527241; called by muse, mutect2, varscan2
- CCDC77 | c.381C>T p.R127= | Silent (SNP) | VAF 91/223 reads (41%) | catalogued as COSV53472058; called by muse, mutect2, varscan2
- CCDC88C | c.3669G>A p.L1223= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV66234718; called by muse, mutect2, varscan2
- CCER1 | c.930G>A p.E310= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs779116554, COSV62646095; called by muse, mutect2, varscan2
- CCND2 | c.747G>A p.Q249= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV54222002; called by muse, mutect2, varscan2
- CD163 | c.3195C>T p.F1065= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as rs763870346, COSV63129316; called by muse, mutect2, varscan2
- CDH20 | c.201C>T p.F67= | Silent (SNP) | VAF 96/245 reads (39%) | catalogued as rs745478230, COSV53005073, COSV53013848; called by muse, mutect2, varscan2
- CDH22 | c.1125C>T p.F375= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs1568659613, COSV64836608; called by muse, mutect2, varscan2
- CEACAM18 | c.936G>A p.R312= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV67282309; called by muse, mutect2, varscan2
- CEACAM21 | c.462C>T p.T154= | Silent (SNP) | VAF 78/169 reads (46%) | catalogued as rs371133723, COSV51813164; called by muse, mutect2, varscan2
- CENPI | c.1896C>T p.F632= | Silent (SNP) | VAF 59/169 reads (35%) | catalogued as COSV54501054; called by muse, mutect2, varscan2
- CEP97 | c.1467A>T p.I489= | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as COSV59122850; called by muse, mutect2, varscan2
- CERS1 | c.622C>T p.L208= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs1297271839, COSV55928678; called by muse, varscan2
- CFH | c.234G>A p.R78= | Silent (SNP) | VAF 133/226 reads (59%) | catalogued as COSV62776441; called by muse, mutect2, varscan2
- CILP | c.1974C>T p.G658= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as COSV56022322; called by muse, mutect2, varscan2
- CLEC5A | c.477C>T p.F159= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as COSV69396853; called by muse, mutect2, varscan2
- CNTNAP4 | c.525C>T p.F175= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs746752739, COSV56667545; called by muse, mutect2, varscan2
- COL11A2 | c.3057A>G p.E1019= (on ENST00000341947 / NM_080680.3; = p.E912= on NM_080679.2) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59494126; called by muse, mutect2, varscan2
- COL12A1 | c.8916G>A p.G2972= | Silent (SNP) | VAF 87/232 reads (38%) | catalogued as COSV59390686; called by muse, mutect2, varscan2
- CPAMD8 | c.2373G>A p.R791= (on ENST00000651564; = p.R744= on NM_015692.5) | Silent (SNP) | VAF 148/359 reads (41%) | catalogued as rs1393510327, COSV52231736; called by muse, mutect2, varscan2
- CRY2 | c.6G>A p.A2= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs765017325, COSV69888173; called by muse, mutect2, varscan2
- CSRNP3 | c.1116G>A p.E372= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as COSV58775670; called by muse, mutect2, varscan2
- CTNND2 | c.3525G>A p.Q1175= | Silent (SNP) | VAF 80/177 reads (45%) | catalogued as rs969785577, COSV58869186; called by muse, mutect2, varscan2
- CTNND2 | c.156C>T p.L52= | Silent (SNP) | VAF 123/267 reads (46%) | catalogued as rs201949668, COSV58873254; called by muse, mutect2, varscan2
- DCSTAMP | c.1230C>G p.P410= | Silent (SNP) | VAF 108/246 reads (44%) | catalogued as COSV99886432; called by muse, mutect2, varscan2
- DDR1 | c.2370C>T p.N790= (on ENST00000324771; = p.N753= on NM_001954.4) | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as COSV61319661; called by muse, mutect2, varscan2
- DHX9 | c.2055C>T p.P685= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV62358440; called by muse, mutect2, varscan2
- DNAH3 | c.11463C>T p.V3821= | Silent (SNP) | VAF 77/188 reads (41%) | catalogued as rs752875810, COSV54506795; called by muse, mutect2, varscan2
- DNAH9 | c.6774G>A p.L2258= | Silent (SNP) | VAF 168/428 reads (39%) | catalogued as rs1276712327, COSV52337177; called by muse, mutect2, varscan2
- DTX1 | c.1359C>T p.L453= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs756576630, COSV55654125; called by muse, mutect2, varscan2
- DTX2 | c.321C>T p.G107= | Silent (SNP) | VAF 69/136 reads (51%) | catalogued as COSV56859198; called by muse, mutect2, varscan2
- DUS3L | c.1539T>C p.G513= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV57831250; called by muse, mutect2, varscan2
- EHD3 | c.729C>T p.I243= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs758911736, COSV59029418; called by muse, mutect2, varscan2
- ELOVL7 | c.435C>T p.F145= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV70917595; called by muse, mutect2, varscan2
- ELP1 | c.3774C>T p.A1258= | Silent (SNP) | VAF 63/76 reads (83%) | catalogued as COSV65896478; called by muse, mutect2, varscan2
- EME1 | c.426C>T p.I142= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as COSV56811734; called by muse, mutect2, varscan2
- EML5 | c.3063C>T p.T1021= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as COSV61342483; called by muse, mutect2, varscan2
- ENTPD6 | c.777C>T p.I259= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs769917395, COSV61751054; called by muse, mutect2, varscan2
- ERG | c.291C>T p.G97= | Silent (SNP) | VAF 68/150 reads (45%) | catalogued as rs146525668; called by muse, mutect2, varscan2
- EVC2 | c.1821C>T p.T607= | Silent (SNP) | VAF 58/155 reads (37%) | catalogued as COSV60388522; called by muse, mutect2, varscan2
- F2RL3 | c.675C>T p.R225= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs759093357, COSV50185212; called by muse, mutect2, varscan2
- FAM131A | c.213C>T p.L71= | Silent (SNP) | VAF 159/423 reads (38%) | catalogued as COSV99658455; called by muse, mutect2, varscan2
- FBXO43 | c.591T>C p.F197= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as COSV71053443; called by muse, mutect2, varscan2
- FCAR | c.255C>T p.F85= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as COSV62028749; called by muse, mutect2, varscan2
- FCER1A | c.699C>T p.L233= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as COSV63666643; called by muse, mutect2, varscan2
- FEZF1 | c.225C>T p.I75= | Silent (SNP) | VAF 58/74 reads (78%) | catalogued as rs1291537900, COSV58658294; called by muse, mutect2, varscan2
- FGF19 | c.495C>T p.F165= | Silent (SNP) | VAF 79/220 reads (36%) | catalogued as COSV53735856; called by muse, mutect2, varscan2
- FGF5 | c.615G>A p.R205= | Silent (SNP) | VAF 77/176 reads (44%) | catalogued as COSV56889268, COSV56892121; called by muse, mutect2, varscan2
- FLT1 | c.3954C>T p.I1318= | Silent (SNP) | VAF 89/198 reads (45%) | catalogued as rs372529662; called by muse, mutect2, varscan2
- FMNL1 | c.2244C>T p.F748= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs750629266, COSV58955487; called by muse, mutect2, varscan2
- FMO1 | c.450T>A p.L150= | Silent (SNP) | VAF 101/238 reads (42%) | catalogued as COSV61444823; called by muse, mutect2, varscan2
- FMO4 | c.342G>A p.T114= | Silent (SNP) | VAF 159/383 reads (42%) | catalogued as rs267598165, COSV63000675; called by muse, mutect2, varscan2
- GAB3 | c.252C>T p.F84= | Silent (SNP) | VAF 173/446 reads (39%) | catalogued as rs1557257582, COSV65818892; called by muse, mutect2, varscan2
- GABRR3 | c.1092G>A p.K364= | Silent (SNP) | VAF 132/379 reads (35%) | catalogued as COSV72084015; called by muse, mutect2, varscan2
- GALNT14 | c.573G>A p.Q191= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as COSV61102688; called by muse, mutect2, varscan2
- GFRA1 | c.714G>A p.R238= | Silent (SNP) | VAF 54/70 reads (77%) | catalogued as COSV62602766; called by muse, mutect2, varscan2
- GKAP1 | c.942A>G p.E314= | Silent (SNP) | VAF 84/101 reads (83%) | catalogued as rs924968946, COSV64487292; called by muse, mutect2, varscan2
- GPR39 | c.696C>T p.L232= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as rs144877200, COSV100257943; called by muse, mutect2, varscan2
- GPR50 | c.1533C>T p.S511= | Silent (SNP) | VAF 233/456 reads (51%) | catalogued as rs1027968280, COSV54437301; called by muse, mutect2, varscan2
- GPRC5C | c.135G>A p.R45= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV61235582; called by muse, mutect2, varscan2
- GRIK2 | c.1458G>A p.G486= | Silent (SNP) | VAF 54/82 reads (66%) | catalogued as rs867832831, COSV59715366; called by muse, mutect2, varscan2
- GSPT2 | c.1122G>A p.L374= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV61213772; called by muse, mutect2, varscan2
- GSTA1 | c.543G>A p.L181= | Silent (SNP) | VAF 136/466 reads (29%) | catalogued as COSV58014659; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2409G>A p.R803= (on ENST00000265755 / NM_016328.3; = p.R788= on NM_005685.4) | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV56084800; called by muse, mutect2, varscan2
- HCK | c.1580G>A p.*527= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV52940698; called by muse, mutect2, varscan2
- HIPK1 | c.3549C>T p.S1183= (on ENST00000369558 / NM_001369806.1; = p.S789= on NM_181358.2) | Silent (SNP) | VAF 133/349 reads (38%) | catalogued as COSV61246310; called by muse, mutect2, varscan2
- HKDC1 | c.1752C>T p.F584= | Silent (SNP) | VAF 146/187 reads (78%) | catalogued as COSV63575730; called by muse, varscan2
- HMGB3 | c.531G>A p.R177= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV57485565; called by muse, mutect2, varscan2
- HS6ST3 | c.1206C>T p.F402= | Silent (SNP) | VAF 67/187 reads (36%) | catalogued as COSV65003224; called by muse, mutect2, varscan2
- HTT | c.6003C>T p.F2001= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV61858180; called by muse, mutect2, varscan2
- IGHD | c.78G>A p.L26= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as COSV101162845; called by muse, mutect2, varscan2
- IGKV1-16 | c.288C>T p.T96= | Silent (SNP) | VAF 135/376 reads (36%) | catalogued as rs765998276; called by muse, varscan2
- IGKV1-27 | c.207G>A p.L69= | Silent (SNP) | VAF 93/365 reads (25%) | catalogued as rs377223753; called by muse, varscan2
- IGKV3D-15 | c.24C>T p.L8= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs752427430; called by muse, mutect2, varscan2
- IGLV8-61 | c.273C>T p.S91= | Silent (SNP) | VAF 186/209 reads (89%) | catalogued as COSV66502563; called by muse, mutect2, varscan2
- IL22RA1 | c.1173C>T p.A391= | Silent (SNP) | VAF 81/221 reads (37%) | catalogued as COSV54627690; called by muse, mutect2, varscan2
- IQCA1 | c.1251G>A p.Q417= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV54497186; called by muse, mutect2
- IRF9 | c.453C>T p.N151= | Silent (SNP) | VAF 94/196 reads (48%) | catalogued as COSV60702772; called by muse, mutect2, varscan2
- JCAD | c.2503T>C p.L835= | Silent (SNP) | VAF 84/207 reads (41%) | catalogued as COSV64758247; called by muse, mutect2, varscan2
- KCNH7 | c.1716G>A p.A572= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as rs779191013, COSV59787795; called by muse, mutect2, varscan2
- KCNJ12 | c.588C>T p.F196= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV59164145; called by muse, mutect2, varscan2
- KCNJ15 | c.156A>G p.Q52= | Silent (SNP) | VAF 16/249 reads (6%) | catalogued as COSV60810338; called by muse, mutect2
- KCNK10 | c.1197C>T p.V399= | Silent (SNP) | VAF 64/181 reads (35%) | catalogued as rs1360706344, COSV56640221; called by muse, mutect2, varscan2
- KCNK9 | c.1062C>T p.I354= | Silent (SNP) | VAF 202/349 reads (58%) | catalogued as rs1483350793, COSV57278799, COSV57284405; called by muse, mutect2, varscan2
- KCNN2 | c.384C>T p.F128= (on ENST00000264773; = p.F340= on NM_021614.4) | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs754896683, COSV53284116; called by muse, mutect2, varscan2
- KDM7A | c.1092T>G p.A364= | Silent (SNP) | VAF 79/216 reads (37%) | catalogued as COSV50090242; called by muse, mutect2, varscan2
- KEL | c.897C>T p.F299= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs1217854452, COSV62333596; called by muse, mutect2, varscan2
- KIF26A | c.3759G>A p.Q1253= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as COSV59464800; called by muse, mutect2, varscan2
- KIF26B | c.2808C>T p.I936= | Silent (SNP) | VAF 51/103 reads (50%) | catalogued as rs745847923, COSV63637609; called by muse, mutect2, varscan2
- KLHDC7A | c.1998G>A p.K666= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV68769122; called by muse, mutect2, varscan2
- KLHL25 | c.627G>A p.V209= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as COSV61994321; called by muse, mutect2, varscan2
- KLK6 | c.453C>T p.F151= | Silent (SNP) | VAF 91/205 reads (44%) | catalogued as COSV59564880; called by muse, mutect2, varscan2
- KRT77 | c.1170G>A p.Q390= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV59238624; called by muse, mutect2, varscan2
- LATS2 | c.1098C>T p.S366= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as rs1346802071, COSV66873566; called by muse, mutect2, varscan2
- LHFPL4 | c.294C>T p.F98= | Silent (SNP) | VAF 39/45 reads (87%) | catalogued as rs1271031898, COSV55001038; called by muse, mutect2, varscan2
- LIPE | c.1056G>A p.L352= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV54921595, COSV99733755; called by muse, mutect2, varscan2
- LRCH2 | c.579C>T p.S193= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2
- LRG1 | c.261C>T p.L87= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as rs766054102, COSV56702555, COSV56703918; called by muse, mutect2, varscan2
- LRIG1 | c.2979G>A p.G993= | Silent (SNP) | VAF 103/278 reads (37%) | catalogued as COSV99833559; called by muse, mutect2, varscan2
- LRIT3 | c.975T>C p.D325= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as COSV59983387; called by muse, mutect2, varscan2
- LRRC18 | c.438C>T p.L146= | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as COSV53282278; called by muse, mutect2, varscan2
- LRRC74A | c.1275C>T p.I425= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1168658774, COSV53608126; called by muse, mutect2, varscan2
- LYPLAL1 | c.663G>A p.L221= | Silent (SNP) | VAF 68/198 reads (34%) | catalogued as rs1489417159, COSV65106341; called by muse, mutect2, varscan2
- MAPK4 | c.402C>T p.L134= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as rs575055030, COSV68541244; called by muse, varscan2
- MASP2 | c.1506G>A p.L502= | Silent (SNP) | VAF 138/342 reads (40%) | catalogued as COSV53569194; called by muse, mutect2, varscan2
- MAST4 | c.4110C>T p.S1370= (on ENST00000403625 / NM_001164664.2; = p.S1181= on NM_015183.3) | Silent (SNP) | VAF 106/229 reads (46%) | catalogued as rs779293062, COSV55117386; called by muse, mutect2, varscan2
- MED14 | c.2499T>A p.I833= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV61356016; called by muse, mutect2, varscan2
- MID2 | c.372G>A p.R124= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV99464422; called by muse, mutect2, varscan2
- MINK1 | c.864C>T p.F288= | Silent (SNP) | VAF 88/210 reads (42%) | catalogued as COSV61788829; called by muse, mutect2, varscan2
- MRC2 | c.3183G>A p.G1061= | Silent (SNP) | VAF 67/144 reads (47%) | catalogued as COSV57637253; called by muse, mutect2, varscan2
- MSANTD3 | c.777C>T p.T259= | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as COSV100614606; called by muse, mutect2, varscan2
- MTNR1B | c.963G>A p.R321= | Silent (SNP) | VAF 153/380 reads (40%) | catalogued as rs1310899445, COSV57065532, COSV57066467; called by muse, mutect2, varscan2
- MUC16 | c.10626C>T p.I3542= | Silent (SNP) | VAF 128/388 reads (33%) | catalogued as COSV67449104; called by muse, varscan2
- MXRA5 | c.6306C>T p.F2102= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1346177537, COSV54226058; called by muse, mutect2, varscan2
- MXRA5 | c.2238C>T p.L746= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs760869413, COSV54226081; called by muse, mutect2, varscan2
- MYH9 | c.546G>A p.E182= | Silent (SNP) | VAF 186/218 reads (85%) | catalogued as COSV53382660; called by muse, mutect2, varscan2
- MYO5C | c.657G>A p.G219= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV55903167; called by muse, mutect2, varscan2
- NBPF1 | c.1374C>T p.A458= | Silent (SNP) | VAF 111/982 reads (11%) | catalogued as rs755963232, COSV99844451; called by muse, mutect2, varscan2
159 further variants in this file (0 protein-altering or splice-affecting, 138 silent, 21 other) are not listed here.
